Gene-level copy-number profile of tumor specimen TCGA-06-5416-01A from TCGA case TCGA-06-5416, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.4 years (8,533 days).
Specimen TCGA-06-5416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.9f969372-0fe2-49ab-97c3-df422e3e6b8e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-5416-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 391 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9a82328-9240-4856-b884-2d1ea0d0802c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,667; copy number 1: 17,016; copy number 2: 34,943; copy number 3: 4,396; copy number 4: 191; copy number 5: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-5416-01): tumor purity 0.79, ploidy 3.76, whole-genome doublings 1 (call status: maf_call).

Caution: 3,146 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 3,146 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:153,710,160–153,760,024, 2 genes (within-gene range 0–1): RNF175, AC020703.1.
- chr8:56,160,909–62,249,879, 88 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:62,473,217–62,483,811, 2 genes: AC018861.2, AC018861.1.
- chr8:71,828,167–72,118,393, 1 gene (within-gene range 0–2): MSC-AS1.
- chr8:72,019,917–79,314,951, 98 genes (broad region; genes not listed).
- chr8:94,688,228–95,811,254, 25 genes (within-gene range 0–2): AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1.
- chr8:100,380,486–103,332,866, 87 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:110,899,996–111,236,203, 5 genes: LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37.
- chr8:111,380,603–111,380,868, 1 gene: SERPINA15P.
- chr14:81,221,218–86,401,285, 42 genes: AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2, AL355095.1, AL359238.1, AL162872.1, RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309.
- chr14:87,568,181–106,875,071, 751 genes (broad region; genes not listed).
- chr15:24,101,827–101,933,350, 2,038 genes (broad region; genes not listed).
- chr18:1,655,177–1,779,955, 1 gene (within-gene range 0–2): AC019183.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:124,550,784–125,541,373, 18 genes, copy number 5 (within-gene range 3–5): MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr18:27,418,884–27,420,435, 1 gene, copy number 5: RBM22P1.

Autosomal genes at a single copy (total copy number 1): 14,595. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
